Somatic mutation profile of tumor specimen TCGA-VQ-A8PS-01A (aliquot TCGA-VQ-A8PS-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PS, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 76.8 years (28,035 days).
Specimen TCGA-VQ-A8PS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3353deb8-f953-47e7-b703-8c0e76f6dae0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PS-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PS-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d70df1a3-c383-40c6-815d-8c47867e4b8b

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 15, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100792299; called by muse, mutect2, varscan2
- ANXA10 | c.62T>G p.M21R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100828965, COSV63740511; called by muse, mutect2, varscan2
- BIRC6 | c.2472T>A p.Y824* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101428141; called by muse, mutect2, varscan2
- CDH10 | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100051030; called by muse, mutect2, varscan2
- CYFIP2 | c.1349T>G p.F450C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100556442; called by muse, mutect2, varscan2
- DHX32 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1452117508, COSV99501552; called by muse, mutect2, varscan2
- GABRG2 | c.1094C>T p.S365L (on ENST00000361925 / NM_001375343.1; = p.S325L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62717482; called by muse, mutect2, varscan2
- GTF3C1 | c.4870G>A p.E1624K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as rs747513732, COSV62241458; called by muse, mutect2, varscan2
- HADH | c.135T>A p.V45= | Splice Region (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100531291; called by muse, varscan2
- HCRTR2 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs141639071, COSV63793586, COSV63794792; called by muse, mutect2, varscan2
- HDAC9 | c.1579A>T p.T527S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV101286695, COSV67788633; called by muse, mutect2, varscan2
- HDAC9 | c.1580C>A p.T527N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.139); catalogued as COSV101286696, COSV67766526; called by muse, mutect2, varscan2
- INSRR | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100947394; called by muse, mutect2, varscan2
- KLF12 | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.927); catalogued as COSV100888467; called by muse, mutect2, varscan2
- MANBA | c.1541A>T p.H514L (on ENST00000642252; = p.H468L on NM_005908.4) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV99898582; called by muse, mutect2, varscan2
- MKRN3 | c.822G>C p.L274F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100091035; called by muse, mutect2, varscan2
- MRTFA | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100843969; called by muse, mutect2, varscan2
- MUC6 | c.6601_6603del p.S2201del | In Frame Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs1296850164; called by pindel, varscan2
- MYO18B | c.5956A>T p.I1986F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100123325; called by muse, mutect2, varscan2
- MYOC | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV50676389; called by muse, mutect2, varscan2
- NECAB3 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs1219832988, COSV99864660; called by muse, mutect2, varscan2
- OLFML2B | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as rs750492409, COSV54198425; called by muse, mutect2, varscan2
- PAPOLG | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV99474617; called by muse, mutect2, varscan2
- PLA2G7 | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV99221298; called by muse, mutect2, varscan2
- PSME4 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV101122443; called by muse, mutect2, varscan2
- SETD2 | c.5486A>C p.Q1829P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100338714; called by muse, mutect2, varscan2
- SLC39A12 | c.1724T>C p.I575T (on ENST00000377369 / NM_001145195.2; = p.I538T on NM_152725.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as COSV101070020; called by muse, mutect2
- SLC4A5 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772367349, COSV61026835; called by muse, mutect2, varscan2
- SLITRK5 | c.2812A>T p.K938* | Nonsense Mutation (SNP) | VAF 83/256 reads (32%) | catalogued as COSV100280628; called by muse, mutect2, varscan2
- TGFB1I1 | c.763G>A p.G255R (on ENST00000394863 / NM_001042454.3; = p.G238R on NM_015927.4) | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1310763010, COSV62357942; called by muse, mutect2, varscan2
- ZDHHC14 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63075363; called by muse, varscan2
- PBRM1 | c.773dup p.N258Kfs*6 | Frame Shift Ins (INS) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- ABCA2 | c.2280G>A p.E760= (on ENST00000614293; = p.E730= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99687441; called by muse, mutect2, varscan2
- CATSPER1 | c.1707C>T p.V569= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100375857, COSV56413075; called by muse, mutect2, varscan2
- CR1 | c.1008G>A p.A336= (on ENST00000367051; = p.A786= on NM_000651.6) | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs556651959, COSV100887534; called by mutect2, varscan2
- FGFR4 | c.627C>T p.L209= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV52808368; called by muse, mutect2, varscan2
- GFPT2 | c.1338C>T p.G446= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs775727574, COSV99517572; called by muse, mutect2, varscan2
- HTT | c.6927C>T p.Y2309= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV61869760; called by muse, mutect2
- KIAA0753 | c.1233G>A p.K411= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100810571; called by muse, mutect2, varscan2
- MFSD2A | c.678C>T p.F226= (on ENST00000372809 / NM_001136493.3; = p.F213= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV65685308; called by muse, mutect2, varscan2
- OR10X1 | c.495C>T p.C165= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100936629, COSV100936723; called by muse, mutect2, varscan2
- SIPA1L2 | c.3009C>T p.T1003= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99477925; called by muse, mutect2, varscan2
- SLC8A1 | c.198C>T p.P66= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV100245581; called by muse, mutect2, varscan2
- SLC9C1 | c.888T>C p.T296= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99997753; called by muse, mutect2, varscan2
- SYTL5 | c.384C>T p.F128= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV99937115; called by muse, mutect2, varscan2
- WASHC2C | c.3798C>T p.N1266= (on ENST00000336378; = p.N1245= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- ZNF675 | c.1101C>G p.P367= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV100705012; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852177 G>A | 3'Flank (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SNORD116-10 | n.90C>T | RNA (SNP) | VAF 23/62 reads (37%) | catalogued as rs779168399; called by muse, mutect2, varscan2
